Somatic mutation profile of tumor specimen C3L-04392-03 (aliquot CPT0393310006) from CPTAC case C3L-04392, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 80.8 years (29,515 days).
Specimen C3L-04392-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e9ddc94-e02d-4a27-887b-d2bfedf77b86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04392-31 (Blood Derived Normal), aliquot CPT0392370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0d89f73-16de-483a-9f3b-6ec40ae3c55c

The open-access MAF lists 55 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 13, Nonsense Mutation 3, Intron 3, Frame Shift Del 2, 3'UTR 1, Splice Site 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYS | c.6976C>T p.R2326* | Nonsense Mutation (SNP) | VAF 184/461 reads (40%) | catalogued as rs1060499783, CM157902, COSV65462788; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNG3 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV50065622; called by muse, mutect2, varscan2
- CBLL2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV60369891, COSV60370312; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 67/428 reads (16%) | catalogued as rs775950025; called by mutect2, varscan2
- GALNT18 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1370691131, COSV57144529; called by muse, mutect2, varscan2
- HAUS1 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as rs773290948; called by muse, mutect2, varscan2
- IDH3A | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100211084; called by muse, mutect2, varscan2
- MXRA5 | c.6355C>T p.R2119C | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV54234496; called by muse, mutect2, varscan2
- NRXN1 | c.3674C>T p.T1225M | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1228030187; called by muse, mutect2, varscan2
- OR5H15 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 84/274 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV62948339; called by muse, mutect2, varscan2
- PON2 | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 113/462 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as rs1022670602, COSV99749752; called by muse, mutect2, varscan2
- RAF1 | c.1492G>A p.G498S | Missense Mutation (SNP) | VAF 185/420 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1245182698; called by muse, mutect2, varscan2
- RND3 | c.658A>G p.M220V | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1466682774; called by muse, mutect2, varscan2
- SCUBE1 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs201262266; called by muse, mutect2
- SLC6A5 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 140/267 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.316); catalogued as COSV99040566; called by muse, mutect2, varscan2
- TALDO1 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 54/154 reads (35%) | catalogued as rs1277253228, CD130462; called by muse, mutect2, varscan2
- TDRD12 | c.3384-6G>A | Splice Region (SNP) | VAF 50/144 reads (35%) | catalogued as rs891545013, COSV101471778; called by muse, mutect2, varscan2
- TTLL10 | c.344G>A p.G115E (on ENST00000379289 / NM_001130045.2; = p.G42E on NM_153254.3) | Missense Mutation (SNP) | VAF 93/242 reads (38%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.007); catalogued as COSV64961219; called by muse, mutect2, varscan2
- CUL4A | c.369-1C>G p.X123_splice (on ENST00000375440 / NM_001008895.4; = p.X23_splice on NM_003589.3) | Splice Site (SNP) | VAF 55/82 reads (67%) | called by muse, mutect2, varscan2
- DAPL1 | c.23del p.L8Rfs*13 | Frame Shift Del (DEL) | VAF 44/192 reads (23%) | called by mutect2, pindel, varscan2
- DDX58 | c.1237G>T p.G413C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DEUP1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DOCK5 | c.5569G>C p.A1857P | Missense Mutation (SNP) | VAF 98/163 reads (60%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- DPP10 | c.1790C>A p.A597E | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- GRIN2B | c.2216T>A p.M739K | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- KDM6B | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 103/304 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- KIF13A | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MCM3AP | c.2145C>G p.S715R | Missense Mutation (SNP) | VAF 14/317 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2
- PKNOX2 | c.1354G>A p.V452I | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPWD1 | c.636C>A p.N212K | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- PRAG1 | c.2045G>A p.G682E | Missense Mutation (SNP) | VAF 179/614 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PTPRQ | c.4699G>A p.A1567T (on ENST00000616559; = p.A1525T on NM_001145026.2) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RELCH | c.719A>T p.N240I | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SPG11 | c.2657dup p.Y886* | Nonsense Mutation (INS) | VAF 59/215 reads (27%) | called by mutect2, pindel, varscan2
- TCEA2 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TFR2 | c.1367C>A p.T456N | Missense Mutation (SNP) | VAF 197/742 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- USH2A | c.11747T>A p.F3916Y | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- ANPEP | c.879G>A p.Q293= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as rs1381588909; called by muse, mutect2, varscan2
- AQP12A | c.213C>T p.H71= | Silent (SNP) | VAF 183/478 reads (38%) | catalogued as rs145149435; called by muse, mutect2, varscan2
- ARHGEF18 | c.2721G>A p.A907= (on ENST00000359920 / NM_001130955.2; = p.A803= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 65/202 reads (32%) | catalogued as rs1460235697; called by muse, mutect2, varscan2
- GRAMD1A | c.1161C>G p.L387= | Silent (SNP) | VAF 54/186 reads (29%) | called by muse, mutect2, varscan2
- IGLV1-50 | c.33C>T p.L11= | Silent (SNP) | VAF 74/213 reads (35%) | catalogued as rs571807910; called by muse, mutect2, varscan2
- MAML3 | c.3033G>A p.V1011= | Silent (SNP) | VAF 85/250 reads (34%) | called by muse, mutect2, varscan2
- MIB2 | c.1134C>T p.V378= | Silent (SNP) | VAF 77/290 reads (27%) | called by muse, mutect2, varscan2
- OR5W2 | c.877A>C p.R293= | Silent (SNP) | VAF 56/151 reads (37%) | catalogued as COSV60618256; called by muse, mutect2, varscan2
- PTPRS | c.933C>T p.C311= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as rs201711435, COSV99509355; called by muse, mutect2, varscan2
- RYR3 | c.3489G>A p.L1163= | Silent (SNP) | VAF 64/155 reads (41%) | called by muse, varscan2
- SVEP1 | c.10608C>T p.C3536= | Silent (SNP) | VAF 53/149 reads (36%) | catalogued as COSV52842155; called by muse, mutect2, varscan2
- TEX13A | c.651G>T p.G217= | Silent (SNP) | VAF 101/140 reads (72%) | called by muse, mutect2, varscan2
- TRIM42 | c.1365C>T p.D455= | Silent (SNP) | VAF 57/328 reads (17%) | catalogued as rs188165530, COSV53880262, COSV53885368; called by muse, mutect2, varscan2
- AC010507.1 | chr19:200707 G>A | 3'Flank (SNP) | VAF 21/260 reads (8%) | catalogued as rs1156407773; called by muse, mutect2, varscan2
- AP1G1 | c.643-38A>G | Intron (SNP) | VAF 43/126 reads (34%) | catalogued as rs762257222; called by muse, mutect2, varscan2
- LTBP3 | c.*6_*8del | 3'UTR (DEL) | VAF 52/132 reads (39%) | called by pindel, varscan2
- PARVB | c.712+361G>A | Intron (SNP) | VAF 34/115 reads (30%) | catalogued as rs766955420; called by muse, mutect2, varscan2
- SYNE1 | c.2569-658C>A | Intron (SNP) | VAF 44/105 reads (42%) | called by muse, mutect2, varscan2
